Somatic mutation profile of tumor specimen TARGET-20-PARNXW-03A (aliquot TARGET-20-PARNXW-03A-01D) from TARGET case TARGET-20-PARNXW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,188 days).
Specimen TARGET-20-PARNXW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04167e8f-97d2-47e7-8114-fa9004fb6503.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNXW-14A (Bone Marrow Normal), aliquot TARGET-20-PARNXW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3760e2c-488d-436d-b71b-aee551424799

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- U2AF1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs769567889, COSV52342800; called by muse, mutect2, varscan2
- WT1 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 68/270 reads (25%) | catalogued as CM971595, COSV60065297; called by muse, varscan2
- RUNX1 | c.416_417del p.R139Qfs*46 (on ENST00000344691 / NM_001001890.3; = p.R166Qfs*46 on NM_001754.5) | Frame Shift Del (DEL) | VAF 93/293 reads (32%) | called by mutect2, pindel, varscan2
